Somatic mutation profile of tumor specimen TCGA-EM-A3OA-01A (aliquot TCGA-EM-A3OA-01A-11D-A21Z-08) from TCGA case TCGA-EM-A3OA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 55.5 years (20,284 days).
Specimen TCGA-EM-A3OA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45cd2112-dd76-41f0-a8a8-46dc9ffcc911.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3OA-10A (Blood Derived Normal), aliquot TCGA-EM-A3OA-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b579006-2f0b-475c-8fa2-f6d09df65f69

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 5, 5'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 108/231 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ANK2 | c.4219A>G p.K1407E | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52187937; called by muse, mutect2, varscan2
- JMJD1C | c.2203C>T p.Q735* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV67867506; called by muse, mutect2, varscan2
- MFSD6L | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV61005912; called by muse, mutect2
- OR4X1 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60723874; called by muse, mutect2
- PLEKHG1 | c.3332C>T p.T1111M | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.226); catalogued as rs139978019, COSV62051035; called by muse, mutect2, varscan2
- ASPSCR1 | c.393C>T p.P131= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as rs370178683; called by muse, mutect2, varscan2
- EPG5 | c.1239C>T p.H413= | Silent (SNP) | VAF 73/187 reads (39%) | catalogued as rs991123123, COSV56355881; called by muse, mutect2, varscan2
- HSPA5 | c.903T>C p.S301= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as COSV52338178; called by muse, mutect2, varscan2
- SNTA1 | c.361T>C p.L121= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as rs770998582, COSV54130809; called by muse, mutect2, varscan2
- ZNF785 | c.975C>T p.S325= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV67876610; called by muse, mutect2
- DPPA4 | c.-2G>A | 5'UTR (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100169608; called by muse, mutect2, varscan2
- KANSL2 | c.1348-281G>T | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as COSV101102077; called by muse, mutect2, varscan2
